Somatic mutation profile of tumor specimen TARGET-30-PANZVU-01A (aliquot TARGET-30-PANZVU-01A-01W) from TARGET case TARGET-30-PANZVU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.7 years (1,713 days).
Specimen TARGET-30-PANZVU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e29bef7-cf98-4ea0-9643-a004d6a2b3bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANZVU-10A (Blood Derived Normal), aliquot TARGET-30-PANZVU-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74240947-0615-4bd1-a1ed-ea7cbde170d9

The open-access MAF lists 36 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 8, Frame Shift Del 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AKAP3 | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 88/305 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1288023685, COSV57414186, COSV57420845; called by muse, mutect2, varscan2
- CEP70 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as rs772444973, COSV53874331; called by muse, varscan2
- CTSG | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 64/400 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs764372295, COSV53534671, COSV53537174; called by muse, mutect2, varscan2
- DNAH11 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV60941270; called by muse, mutect2, varscan2
- FRMD4B | c.1907C>A p.T636N | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV68328458; called by muse, mutect2, varscan2
- GMEB2 | c.950C>A p.A317E | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56605822; called by muse, mutect2, varscan2
- GZMB | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV53539929; called by muse, mutect2
- KLK8 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs144236055, COSV51593993; called by muse, mutect2, varscan2
- LGI1 | c.1438C>A p.Q480K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65057473; called by muse, mutect2, varscan2
- MTA2 | c.1678C>T p.R560W | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs750362468, COSV53468834; called by muse, mutect2, varscan2
- NDST4 | c.2276C>A p.A759D | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV52109674; called by mutect2, varscan2
- NLRP8 | c.1569C>A p.F523L | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV52583500, COSV52583615; called by muse, mutect2, varscan2
- OR2T3 | c.581G>T p.C194F | Missense Mutation (SNP) | VAF 285/810 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62081808; called by muse, mutect2, varscan2
- OR52E4 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV57623939; called by muse, mutect2, varscan2
- PACSIN2 | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54316275; called by muse, mutect2, varscan2
- PLEKHH2 | c.3319C>A p.L1107I | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV56749978; called by muse, mutect2, varscan2
- PPP4R4 | c.2011-1G>T p.X671_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV58552038; called by muse, mutect2, varscan2
- SGK1 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV52805253; called by muse, mutect2, varscan2
- SPTBN4 | c.3688A>G p.T1230A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV58943949; called by muse, mutect2, varscan2
- USH2A | c.11354G>T p.G3785V | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56330958, COSV56453941; called by muse, mutect2, varscan2
- ADAMTS3 | c.551T>C p.L184S | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AZI2 | c.1102A>G p.K368E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.437); called by muse, mutect2
- LHPP | c.727del p.E243Sfs*6 | Frame Shift Del (DEL) | VAF 29/147 reads (20%) | called by mutect2, pindel, varscan2
- OR5B3 | c.523T>A p.F175I | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC25A28 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- BCOR | c.3225C>T p.N1075= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs375752421, COSV60700732; called by muse, mutect2, varscan2
- CYFIP1 | c.1089G>T p.L363= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- DRD1 | c.1170G>T p.L390= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as COSV67104239; called by muse, mutect2, varscan2
- LBX1 | c.528G>A p.R176= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV64621487; called by muse, mutect2, varscan2
- MUC16 | c.10410C>A p.G3470= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV67446777; called by muse, mutect2, varscan2
- NDUFAF7 | c.546C>A p.S182= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV50018101; called by muse, mutect2, varscan2
- NXPE1 | c.1527C>A p.L509= (on ENST00000424269; = p.L367= on NM_152315.5) | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV52627058; called by muse, mutect2, varscan2
- STOML3 | c.774C>T p.T258= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs377663641, COSV65509979; called by muse, mutect2, varscan2
- CDKL1 | c.171+18096C>A | Intron (SNP) | VAF 31/105 reads (30%) | catalogued as COSV53578022; called by muse, mutect2, varscan2
- OR3A4P | n.755C>A | RNA (SNP) | VAF 34/296 reads (11%) | called by muse, mutect2, varscan2
